Surgical pathology report (de-identified scan), TCGA case TCGA-RW-A68D, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Michigan University, specimen TCGA-RW-A68D-01A (Primary Tumor).

PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE: 1
NAME: '
BIRTHDATE:

PAGE #: 1
SEX: F
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

PROCEDURE: SPHS

VERIFIED BY:

-year-old female status post C-section ago, afterward
developed cardiogenic shock. Lab work-up showed pheochromocytoma. Operative
procedure: Left adrenalectomy.

PROCEDURE: SPGD

VERIFIED BY:

1. "Left adrenal gland" Received in a medium container is a 29.13 gram, 6.5 x
3.6 x 2.9 cm with a 4.0 x 2.6 x 2.3 cm tan homogenous nodule. No hemorrhage or
necrosis. Peripheral rim of renal gland with coppery tan cortex, brown
medulla.

1A.-E. Nodule with respect to uninvolved adrenal gland and capsule. (

PROCEDURE: SPDX

VERIFIED BY:

1. Left adrenal gland, adrenalectomy: Pheochromocytoma.

I, the signing staff pathologist, have personally
examined and interpreted the slides from this case.

Code.

ICD-O-3

Pheochromocytoma NOS 8700/0
Site (L) Adrenal gland NOS C74.9
W 12/13/13

Source: NCI Genomic Data Commons file 34468287-01e0-4f89-90a7-5667af43856b (TCGA-RW-A68D.D7FF4981-4F40-441C-946E-F0931BD026F2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).